Somatic mutation profile of tumor specimen TCGA-12-3652-01A (aliquot TCGA-12-3652-01A-01W-0922-08) from TCGA case TCGA-12-3652, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.0 years (21,920 days).
Specimen TCGA-12-3652-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 99628e19-e8a4-4cb0-a9bb-b4e1ace8faf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-12-3652-10A (Blood Derived Normal), aliquot TCGA-12-3652-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4d9c992e-858c-4635-9bfd-6c8cfa499e87

The open-access MAF lists 67 somatic variants for this specimen: 48 protein-altering or splice-affecting, 16 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 16, Nonsense Mutation 5, Intron 3, In Frame Del 1, Nonstop Mutation 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAV3 | c.244G>A p.V82I | Missense Mutation (SNP) | VAF 36/67 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs112626848, CM139930, COSV57479298; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.755G>C p.R252P | Missense Mutation (SNP) | VAF 90/865 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.868); catalogued as COSV51785413, COSV51800797; called by muse, mutect2, varscan2
- AC126283.2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67097947; called by muse, mutect2, varscan2
- ADCY10 | c.2863C>T p.R955C | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.791); catalogued as rs1388091820, COSV63244738; called by muse, mutect2, varscan2
- ALMS1 | c.3994A>G p.T1332A | Missense Mutation (SNP) | VAF 138/297 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1211259619, COSV52521480; called by muse, mutect2, varscan2
- BNC2 | c.2665C>T p.R889C | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs779084645, COSV66175816; called by muse, mutect2, varscan2
- C3 | c.4985C>A p.P1662H | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1339837166, CM1313440, COSV55574230; called by muse, mutect2, varscan2
- CCDC60 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 162/349 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs750397643, COSV59547587; called by muse, mutect2, varscan2
- CDH9 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 63/74 reads (85%) | catalogued as COSV50254724; called by muse, mutect2, varscan2
- ESYT1 | c.2703G>T p.Q901H | Missense Mutation (SNP) | VAF 92/199 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.421); catalogued as rs1231415486, COSV57276295; called by muse, mutect2, varscan2
- FAM135B | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 29/180 reads (16%) | catalogued as COSV52752227; called by muse, mutect2, varscan2
- FAT1 | c.6638A>T p.K2213I | Missense Mutation (SNP) | VAF 332/659 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.912); catalogued as COSV71675932; called by muse, mutect2, varscan2
- FKBP8 | c.605C>T p.T202M (on ENST00000222308 / NM_001308373.2; = p.T203M on NM_012181.5) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.227); catalogued as rs201710065, COSV55892188; called by muse, mutect2, varscan2
- GALK2 | c.1198A>G p.T400A | Missense Mutation (SNP) | VAF 231/517 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54819202; called by muse, mutect2, varscan2
- GLUL | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59381975; called by muse, mutect2, varscan2
- HHIPL2 | c.1579C>T p.R527* | Nonsense Mutation (SNP) | VAF 28/71 reads (39%) | catalogued as rs779253171, COSV58563608, COSV58567693; called by muse, mutect2, varscan2
- HLX | c.1037A>G p.E346G | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV65045637; called by muse, mutect2, varscan2
- INPP1 | c.1200G>C p.*400Yext*10 | Nonstop Mutation (SNP) | VAF 47/103 reads (46%) | catalogued as COSV59417460; called by muse, mutect2, varscan2
- KDM5D | c.919A>T p.S307C | Missense Mutation (SNP) | VAF 165/183 reads (90%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as COSV58737271; called by muse, mutect2, varscan2
- KLF12 | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 134/422 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.827); catalogued as COSV66581375; called by muse, mutect2, varscan2
- LINGO2 | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 138/163 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.075); catalogued as rs1016504624, COSV58064143; called by muse, mutect2, varscan2
- MTX3 | c.402G>C p.L134F | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.16); PolyPhen benign (0.401); catalogued as COSV72512201, COSV72512513; called by mutect2, varscan2
- MUC5AC | c.13604C>G p.A4535G | Missense Mutation (SNP) | VAF 11/13 reads (85%) | SIFT tolerated (0.44); catalogued as rs767920306; called by muse, varscan2
- NOD1 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 58/136 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs139576372, COSV56114694; called by muse, mutect2, varscan2
- NPFFR2 | c.1012G>T p.V338F | Missense Mutation (SNP) | VAF 100/253 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.688); catalogued as COSV58154132; called by muse, mutect2, varscan2
- NPHS1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs751182197, COSV62289800; called by muse, mutect2, varscan2
- NRK | c.3827A>T p.H1276L | Missense Mutation (SNP) | VAF 20/22 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as rs35942881, COSV99688547; called by muse, varscan2
- OR5AN1 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 187/487 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58322785; called by muse, mutect2, varscan2
- OR9G1 | c.81del p.F27Lfs*13 | Frame Shift Del (DEL) | VAF 66/409 reads (16%) | catalogued as COSV100380451, COSV56447576; called by mutect2, pindel*, varscan2
- PCDH7 | c.3067G>T p.D1023Y | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62343300; called by muse, mutect2, varscan2
- PCDH9 | c.3302A>G p.K1101R (on ENST00000377865 / NM_203487.3; = p.K1067R on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/124 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.304); catalogued as COSV60588475; called by muse, mutect2, varscan2
- PROKR2 | c.506C>T p.T169M | Missense Mutation (SNP) | VAF 212/580 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.919); catalogued as rs527771034, COSV54086678; called by muse, mutect2, varscan2
- RFX6 | c.1682C>T p.A561V | Missense Mutation (SNP) | VAF 81/216 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs201446493, COSV60584103; called by muse, mutect2, varscan2
- RNF17 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs752488820, COSV55050835; called by muse, mutect2, varscan2
- SHPRH | c.4628T>C p.I1543T (on ENST00000275233 / NM_001042683.3; = p.I1547T on NM_173082.3) | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1326785662, COSV51617375; called by muse, mutect2, varscan2
- SIM1 | c.1642C>T p.R548* | Nonsense Mutation (SNP) | VAF 110/248 reads (44%) | catalogued as COSV53492971; called by muse, mutect2, varscan2
- SLC24A1 | c.797C>A p.A266E | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV56053994; called by muse, mutect2, varscan2
- SLC2A4RG | c.531dup p.E178Rfs*56 | Frame Shift Ins (INS) | VAF 4/27 reads (15%) | catalogued as rs748002768; called by pindel, varscan2
- UMODL1 | c.151G>C p.V51L | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.541); catalogued as COSV101253316, COSV68577815; called by muse, mutect2, varscan2
- VSIG10 | c.869G>T p.C290F | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63654406; called by muse, mutect2, varscan2
- WFDC8 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 175/550 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.828); catalogued as rs371165838; called by muse, mutect2, varscan2
- WNT2 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761310626, COSV55411711; called by muse, mutect2, varscan2
- ZNF418 | c.67A>T p.S23C | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV68676458; called by muse, mutect2, varscan2
- ELOVL3 | c.154C>T p.Q52* | Nonsense Mutation (SNP) | VAF 22/180 reads (12%) | called by muse, mutect2
- RYR2 | c.5997_6008del p.F1999_D2002del | In Frame Del (DEL) | VAF 43/144 reads (30%) | called by mutect2, pindel, varscan2
- SGK1 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.101); called by muse, mutect2
- TNRC6B | c.337C>G p.P113A | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ZNF658 | c.38T>C p.V13A | Missense Mutation (SNP) | VAF 25/221 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- ADGRV1 | c.3174A>G p.G1058= | Silent (SNP) | VAF 256/576 reads (44%) | catalogued as COSV67994839; called by muse, mutect2
- AR | c.2295C>T p.F765= | Silent (SNP) | VAF 107/255 reads (42%) | catalogued as rs369390411, CM921035, COSV65953823; called by muse, mutect2, varscan2
- KLB | c.834G>A p.S278= | Silent (SNP) | VAF 57/126 reads (45%) | catalogued as rs761233375, COSV57305045; called by muse, mutect2, varscan2
- LRRC55 | c.358C>T p.L120= | Silent (SNP) | VAF 29/68 reads (43%) | catalogued as rs933090902, COSV73006969; called by muse, mutect2, varscan2
- MAN2B2 | c.198C>T p.R66= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs779997292, COSV53454200; called by muse, mutect2, varscan2
- MYO15A | c.6981G>A p.S2327= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs377504192; called by muse, varscan2
- MYO1D | c.108G>A p.G36= | Silent (SNP) | VAF 33/90 reads (37%) | catalogued as COSV59022959; called by muse, mutect2, varscan2
- NR4A1 | c.444G>T p.P148= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV54487506; called by muse, mutect2, varscan2
- PCDHA12 | c.1611G>A p.A537= | Silent (SNP) | VAF 82/158 reads (52%) | catalogued as rs1554169304, COSV56526373; called by muse, mutect2, varscan2
- RBBP8 | c.684T>C p.Y228= | Silent (SNP) | VAF 102/258 reads (40%) | catalogued as rs199995388, COSV59095910; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RNFT2 | c.765C>T p.D255= | Silent (SNP) | VAF 394/1010 reads (39%) | catalogued as rs754486519, COSV57490136; called by muse, mutect2, varscan2
- RPL32 | c.180T>C p.Y60= | Silent (SNP) | VAF 160/335 reads (48%) | catalogued as COSV55994280; called by muse, mutect2, varscan2
- RYR2 | c.12540C>T p.G4180= | Silent (SNP) | VAF 189/461 reads (41%) | catalogued as rs772125105, COSV63694292; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMG2 | c.993A>G p.T331= | Silent (SNP) | VAF 104/364 reads (29%) | catalogued as COSV65647939; called by muse, mutect2, varscan2
- SLC4A1 | c.1215C>T p.V405= | Silent (SNP) | VAF 41/105 reads (39%) | catalogued as rs747517534, COSV52263004; called by muse, mutect2, varscan2
- ZNF385D | c.174G>A p.P58= | Silent (SNP) | VAF 79/152 reads (52%) | catalogued as rs757564443, COSV55774000; called by muse, mutect2, varscan2
- CCSER1 | c.2094+23141G>C | Intron (SNP) | VAF 274/436 reads (63%) | catalogued as COSV61466409; called by muse, varscan2
- PSG1 | c.1243+361A>T | Intron (SNP) | VAF 31/92 reads (34%) | catalogued as COSV99740848; called by muse, mutect2, varscan2
- SON | c.6657+211A>G | Intron (SNP) | VAF 30/61 reads (49%) | catalogued as COSV99279213; called by muse, mutect2, varscan2
